Gene-level copy-number profile of tumor specimen ALCH-B1YH-TTP1-A from ALCHEMIST case ALCH-B1YH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.2 years (24,191 days).
Specimen ALCH-B1YH-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 288c382d-f7eb-4ba4-a01d-de209a3e1dd8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1YH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,248 have no estimate.
https://portal.gdc.cancer.gov/files/5f282287-ad7c-4abe-8be6-ed1ad33c15c6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 27,090; copy number 2: 29,962; copy number 3: 1,245; copy number 4: 43; copy number 5: 2; copy number 6: 16.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,953,590–118,185,228, 1 gene (within-gene range 0–1): SPAG17.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–1): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:97,737,894–97,738,913, 1 gene: AC112203.1.
- chr14:97,427,071–97,978,124, 6 genes: LINC02325, LINC02291, AL163872.1, LINC02312, AL355097.1, LINC01550.
- chr16:72,236,281–72,665,014, 1 gene (within-gene range 0–1): LINC01572.
- chr16:72,376,704–72,533,892, 2 genes: U6, AC004158.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,297,862–153,541,765, 16 genes, copy number 6: PGLYRP3, PGLYRP4, RNU6-160P, S100A9, S100A12, LAPTM4BP1, S100A8, S100A15A, S100A7A, S100A7P1, S100A7L2, S100A7, RN7SL44P, BX470102.1, S100A6, S100A5.
- chr14:105,621,116–105,621,180, 1 gene, copy number 5: MIR8071-1.
- chr14:105,664,633–105,669,843, 1 gene, copy number 5 (within-gene range 1–5): IGHGP.

Autosomal genes at a single copy (total copy number 1): 24,768. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
